Somatic mutation profile of tumor specimen TARGET-10-PAPZUE-03A (aliquot TARGET-10-PAPZUE-03A-01D) from TARGET case TARGET-10-PAPZUE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,444 days).
Specimen TARGET-10-PAPZUE-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03479365-b487-414e-aaee-7c24ac11d9ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZUE-10A (Blood Derived Normal), aliquot TARGET-10-PAPZUE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5200a424-17f3-49b0-91d0-24729d230c2f

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, In Frame Del 1, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- DAB2IP | c.2305G>A p.V769I (on ENST00000408936; = p.V741I on NM_032552.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs761619061, COSV52265360; called by muse, mutect2, varscan2
- LRRC9 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs749979554; called by muse, mutect2, varscan2
- NSD3 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs752124291; called by muse, mutect2
- PRDM2 | c.4209_4213delinsCC p.N1404_F1405delinsL | In Frame Del (DEL) | VAF 32/82 reads (39%) | called by pindel, varscan2*
- ANK3 | c.7248G>A p.V2416= | Silent (SNP) | VAF 33/203 reads (16%) | called by muse, mutect2, varscan2
- DCX | c.-22-11C>T | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
- GBP2 | c.428+12dup | Intron (INS) | VAF 23/85 reads (27%) | catalogued as rs1557442233; called by mutect2, pindel, varscan2
- KIR2DL1 | chr19:54786569 T>C | 3'Flank (SNP) | VAF 22/156 reads (14%) | catalogued as rs1454761761; called by muse, mutect2, varscan2
